Somatic mutation profile of tumor specimen TCGA-CJ-4641-01A (aliquot TCGA-CJ-4641-01A-02D-1386-10) from TCGA case TCGA-CJ-4641, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 55.9 years (20,410 days).
Specimen TCGA-CJ-4641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0028c21-4625-4870-b094-bcef11d0cf44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4641-11A (Solid Tissue Normal), aliquot TCGA-CJ-4641-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5953d5d-1658-489b-9885-f9025aa5568b

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Splice Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 11/269 reads (4%) | catalogued as COSV62791910; called by muse, mutect2
- ADAMTS12 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61280245; called by muse, mutect2
- ALDH18A1 | c.2208A>C p.G736= | Splice Region (SNP) | VAF 30/180 reads (17%) | catalogued as COSV64663681; called by muse, mutect2
- ARFGAP2 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 86/597 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs369493716; called by muse, mutect2, varscan2
- AXIN2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.307); catalogued as COSV61061214; called by muse, mutect2, varscan2
- BAP1 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56240800; called by muse, mutect2, varscan2
- C20orf194 | c.1930G>T p.V644F | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52703081; called by muse, mutect2
- CALD1 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV62654243; called by muse, mutect2, varscan2
- CR1 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as rs200621891, COSV65462323; called by muse, mutect2, varscan2
- DNAH7 | c.11462A>C p.E3821A | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56786789; called by muse, mutect2, varscan2
- DPP10 | c.246C>G p.H82Q | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV59678240, COSV59729083; called by muse, varscan2
- DUSP5 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV63647530; called by muse, mutect2
- DUSP5 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63647543; called by muse, mutect2, varscan2
- EHBP1L1 | c.635A>C p.D212A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV58575169; called by mutect2, varscan2
- FAT1 | c.12103G>A p.G4035S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71676070; called by muse, mutect2
- FAXDC2 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58174043; called by muse, mutect2, varscan2
- GJA3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53836705; called by muse, varscan2
- HOOK3 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 38/202 reads (19%) | catalogued as COSV56888021; called by muse, mutect2, varscan2
- IST1 | c.653A>C p.K218T (on ENST00000535424 / NM_001270976.1; = p.K205T on NM_014761.4) | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV61711166; called by muse, mutect2
- KCNQ5 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1458098774, COSV59683265; called by muse, mutect2
- KCNQ5 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59683270; called by muse, mutect2
- MAMLD1 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV53380905; called by muse, mutect2, varscan2
- MAPK15 | c.265T>A p.Y89N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62030285; called by muse, mutect2, varscan2
- MAST2 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1250923146, COSV63621499; called by muse, mutect2
- NFE2L3 | c.2076G>T p.K692N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV50239607; called by muse, mutect2, varscan2
- OLFM4 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV54580598; called by muse, mutect2, varscan2
- PADI2 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.19); catalogued as rs754140680, COSV100971037; called by muse, mutect2
- PIGR | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62905087; called by muse, mutect2, varscan2
- RBCK1 | c.931G>A p.G311S (on ENST00000356286 / NM_031229.4; = p.G269S on NM_006462.6) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as COSV62293405; called by muse, mutect2, varscan2
- SPAG4 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV65331118; called by muse, mutect2, varscan2
- SPTA1 | c.4738-1G>C p.X1580_splice | Splice Site (SNP) | VAF 35/500 reads (7%) | catalogued as COSV63759639; called by muse, mutect2
- TAS2R31 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV66831275; called by muse, mutect2, varscan2
- TMCO2 | c.121T>A p.L41M | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV65647027; called by muse, mutect2, varscan2
- XPO1 | c.243A>T p.Q81H | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV68947891; called by muse, mutect2, varscan2
- ZEB2 | c.2093A>G p.Y698C | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.819); catalogued as rs780113721, COSV100356520; called by muse, mutect2, varscan2
- ZNF623 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV71697362; called by muse, mutect2, varscan2
- BANF2 | c.187_193delinsGTGGCTC p.W63_I65delinsVAL | Missense Mutation (ONP) | VAF 33/382 reads (9%) | called by pindel, varscan2*
- CACNA1I | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD6 | c.3961del p.S1321Lfs*29 | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- IGF1R | c.3048_3058del p.V1017Cfs*5 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel
- OR4D11 | c.227_228del p.T76Nfs*4 | Frame Shift Del (DEL) | VAF 42/318 reads (13%) | called by pindel, varscan2
- ABRA | c.687G>A p.E229= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV61732358, COSV61732643; called by muse, mutect2
- CFAP53 | c.24C>T p.T8= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs1047623038, COSV54007075; called by muse, mutect2, varscan2
- EMC3 | c.711C>T p.V237= | Silent (SNP) | VAF 63/316 reads (20%) | catalogued as rs113658691; called by muse, mutect2, varscan2
- GCNA | c.1299T>C p.N433= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as rs1299601701, COSV65468333; called by muse, mutect2, varscan2
- MCM4 | c.2565G>T p.V855= | Silent (SNP) | VAF 32/249 reads (13%) | catalogued as COSV50632832; called by muse, mutect2, varscan2
- NFATC4 | c.1986C>T p.V662= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV51611557; called by muse, mutect2, varscan2
- PABPC3 | c.165G>A p.A55= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs758193253, COSV55805477; called by muse, mutect2, varscan2
- PCDHA8 | c.531C>T p.Y177= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV65340517; called by muse, mutect2, varscan2
- PCDHGA7 | c.1539C>T p.V513= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV54035734; called by muse, mutect2, varscan2
- PLB1 | c.423G>A p.L141= | Silent (SNP) | VAF 47/309 reads (15%) | catalogued as COSV59835818; called by muse, mutect2, varscan2
- PNLIPRP1 | c.840T>C p.N280= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as COSV62613502; called by muse, mutect2
- ADSS1 | c.193-5074G>T | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV58276400; called by muse, varscan2
- DENND1B | c.83-20511G>T | Intron (SNP) | VAF 41/269 reads (15%) | catalogued as COSV99345006; called by muse, mutect2, varscan2
- OR52A4P | chr11:5121148 A>G | 3'Flank (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
